Somatic mutation profile of tumor specimen TCGA-60-2707-01A (aliquot TCGA-60-2707-01A-01D-1522-08) from TCGA case TCGA-60-2707, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.5 years (25,758 days).
Specimen TCGA-60-2707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 471c0dc1-1b9e-465f-b1ed-11c41fd51bc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2707-11A (Solid Tissue Normal), aliquot TCGA-60-2707-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1872d342-e241-4a57-b16a-f7c4ee468234

The open-access MAF lists 99 somatic variants for this specimen: 74 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 21, Nonsense Mutation 6, Splice Site 4, Intron 1, 3'UTR 1, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7474C>T p.Q2492* (on ENST00000358273 / NM_001042492.3; = p.Q2471* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | catalogued as rs1555536340, CM032013, COSV62193242; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123316, CM110129, COSV64290165, COSV64300390, COSV64310812; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3633C>G p.N1211K | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.674); catalogued as COSV55593882, COSV55602024; called by muse, mutect2, varscan2
- AC090517.4 | c.476C>A p.S159* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV51001153, COSV99974614; called by muse, mutect2, varscan2
- ADAMTS12 | c.3443C>T p.T1148I | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61256251, COSV61263358; called by muse, mutect2, varscan2
- ADAMTS20 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs779152806, COSV67140075; called by muse, mutect2, varscan2
- ADAMTS8 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 90/411 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57291496, COSV99961715; called by muse, mutect2, varscan2
- ALPK3 | c.4190G>A p.C1397Y | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV51930230; called by muse, mutect2, varscan2
- ALPK3 | c.4469G>T p.R1490L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV51930249; called by muse, mutect2, varscan2
- AMPD3 | c.184G>T p.E62* (on ENST00000396553 / NM_001025389.2; = p.E71* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV67329986; called by muse, mutect2, varscan2
- ANKRD50 | c.2605C>A p.Q869K | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.18); catalogued as COSV72385092; called by muse, mutect2, varscan2
- ARMCX2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV57529345; called by muse, mutect2, varscan2
- BARX2 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV55649424; called by muse, mutect2, varscan2
- BMPER | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51811279; called by muse, mutect2, varscan2
- CCN6 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57888784; called by muse, mutect2, varscan2
- CDH13 | c.850T>C p.Y284H | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51871274; called by muse, mutect2, varscan2
- CHAT | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60320564; called by muse, mutect2, varscan2
- CLCA1 | c.2243C>A p.P748H | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV52325409, COSV52331460; called by muse, mutect2, varscan2
- COG1 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV55428385; called by muse, mutect2, varscan2
- COL6A2 | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV55999767; called by muse, mutect2, varscan2
- CPLANE1 | c.8230A>G p.I2744V | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV57053086; called by muse, mutect2, varscan2
- CRYBG1 | c.4709A>T p.H1570L | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV64814795; called by muse, mutect2, varscan2
- CSMD2 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.556); catalogued as COSV53883241; called by muse, mutect2, varscan2
- CUBN | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV64708590; called by muse, mutect2, varscan2
- DGKA | c.2004C>G p.I668M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59388856; called by muse, mutect2
- DLG5 | c.2726A>G p.D909G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV64946903; called by muse, mutect2, varscan2
- ERCC6 | c.2091A>T p.L697F | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63388050; called by muse, mutect2, varscan2
- F13B | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201195929, COSV66375813; called by muse, mutect2
- FEZF1 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.156); catalogued as COSV58658250; called by muse, mutect2, varscan2
- FGF10 | c.584A>T p.K195I | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV52940067; called by muse, mutect2
- GFI1 | c.1188C>A p.F396L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54041814; called by muse, mutect2, varscan2
- GRID1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422356227, COSV60012681; called by muse, mutect2
- HBD | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV53082010; called by muse, mutect2, varscan2
- HSPA2 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55968865; called by muse, mutect2, varscan2
- IARS1 | c.3382G>C p.E1128Q | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs929075150, COSV65113552; called by muse, mutect2
- KIF21A | c.945C>G p.S315R | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV62767633; called by muse, mutect2, varscan2
- KRT33A | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs143073969, COSV50373211; called by muse, mutect2
- LHX9 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61326934; called by muse, mutect2, varscan2
- LRIG1 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56237177; called by muse, mutect2, varscan2
- LRRK1 | c.3560A>T p.Y1187F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV52602882, COSV99438158; called by muse, mutect2, varscan2
- MMP16 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV54152271; called by muse, mutect2, varscan2
- MTNR1B | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs878989131, COSV57068730; called by muse, mutect2
- NECTIN4 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV63511980; called by muse, mutect2, varscan2
- NPTXR | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs887146414, COSV60727763; called by muse, mutect2, varscan2
- OR5K3 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as COSV67349714, COSV67349737, COSV67349776; called by muse, mutect2, varscan2
- OR5K3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.461); catalogued as COSV67349600, COSV67349718; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.238G>T p.E80* (on ENST00000259318 / NM_001136562.3; = p.E311* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 75/235 reads (32%) | catalogued as COSV52173657; called by muse, mutect2, varscan2
- PAPPA2 | c.3151G>T p.V1051L | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62791320; called by muse, mutect2, varscan2
- PCNX2 | c.3459G>A p.W1153* | Nonsense Mutation (SNP) | VAF 30/154 reads (19%) | catalogued as COSV50906588; called by muse, mutect2, varscan2
- PCNX2 | c.3458G>T p.W1153L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50907055; called by muse, mutect2, varscan2
- PIK3C2B | c.3623A>G p.H1208R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV65809299; called by muse, mutect2, varscan2
- PRDM16 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54579794; called by muse, mutect2, varscan2
- PRPF4B | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV61783451; called by muse, mutect2, varscan2
- REPIN1 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV68293026; called by muse, mutect2, varscan2
- RFTN2 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54386085; called by muse, mutect2, varscan2
- RHBDL3 | c.668+1G>C p.X223_splice | Splice Site (SNP) | VAF 41/149 reads (28%) | catalogued as COSV52184694; called by muse, mutect2, varscan2
- RNF19A | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV61994929; called by muse, mutect2
- RYR3 | c.2813C>A p.A938D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV66809444; called by muse, mutect2
- SDR42E1 | c.694C>G p.H232D | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61093783; called by muse, mutect2, varscan2
- SLC26A7 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52586912; called by muse, mutect2, varscan2
- SLC39A12 | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101070170, COSV66195404; called by muse, mutect2, varscan2
- SLC4A1 | c.1891-2A>G p.X631_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52258484; called by muse, mutect2, varscan2
- SLC6A11 | c.392-1G>T p.X131_splice | Splice Site (SNP) | VAF 96/291 reads (33%) | catalogued as COSV54390155; called by muse, mutect2, varscan2
- SLC6A11 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54390164; called by muse, mutect2, varscan2
- SMG1 | c.3856C>G p.Q1286E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.206); catalogued as COSV67174955; called by muse, mutect2
- SPTA1 | c.5657T>C p.L1886P | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63749352; called by muse, mutect2, varscan2
- TBC1D21 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV55994597, COSV55994712; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 106/293 reads (36%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TPR | c.2363A>T p.K788M | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66599594; called by muse, mutect2, varscan2
- TRPM6 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV62523438; called by muse, mutect2
- VRK2 | c.857-2A>T p.X286_splice | Splice Site (SNP) | VAF 24/118 reads (20%) | catalogued as COSV60874847; called by muse, mutect2, varscan2
- VWA3B | c.2635G>T p.V879F | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370362777, COSV68241082; called by muse, mutect2, varscan2
- IGKV6D-21 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV1-47 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ACSM5 | c.1056T>C p.P352= | Silent (SNP) | VAF 45/177 reads (25%) | catalogued as COSV59369700; called by muse, mutect2, varscan2
- ADH1B | c.1026A>G p.S342= | Silent (SNP) | VAF 46/211 reads (22%) | catalogued as COSV59298951; called by muse, mutect2, varscan2
- ARSG | c.819C>T p.L273= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV71594023; called by muse, mutect2
- CCDC27 | c.534C>A p.G178= | Silent (SNP) | VAF 50/302 reads (17%) | catalogued as COSV53903877; called by muse, mutect2, varscan2
- ETS1 | c.159C>T p.F53= | Silent (SNP) | VAF 14/240 reads (6%) | catalogued as COSV60098100; called by muse, mutect2
- ETV1 | c.924C>G p.V308= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as COSV54152066; called by muse, mutect2
- GALC | c.1221A>G p.Q407= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs747714175, COSV54323263; called by muse, mutect2, varscan2
- GATA1 | c.1131C>T p.S377= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV64961542; called by muse, mutect2, varscan2
- GCSAML | c.19C>A p.R7= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as COSV63577121, COSV63577142; called by muse, mutect2, varscan2
- GRSF1 | c.753G>A p.V251= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV54657328; called by muse, mutect2, varscan2
- HERC2 | c.846C>A p.P282= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV55309190; called by muse, mutect2, varscan2
- MED12L | c.2220A>G p.A740= | Silent (SNP) | VAF 150/679 reads (22%) | catalogued as COSV56369542; called by muse, mutect2, varscan2
- MTOR | c.3987G>C p.L1329= | Silent (SNP) | VAF 41/164 reads (25%) | catalogued as COSV63868732; called by muse, mutect2, varscan2
- MYBL1 | c.1341C>G p.L447= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as COSV72919244; called by muse, mutect2, varscan2
- OR10AG1 | c.579A>T p.V193= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV56631630; called by muse, mutect2, varscan2
- PLAGL2 | c.1221C>T p.L407= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV55787493; called by muse, mutect2
- SLC35F5 | c.1122A>G p.L374= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs752592823, COSV55517012; called by muse, mutect2, varscan2
- SORBS2 | c.1788C>T p.S596= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs1223387064, COSV52992070; called by muse, mutect2, varscan2
- ST8SIA6 | c.222G>T p.S74= | Silent (SNP) | VAF 79/374 reads (21%) | catalogued as COSV66461131; called by muse, mutect2, varscan2
- SYNE1 | c.2577A>G p.L859= (on ENST00000367255 / NM_182961.4; = p.L866= on NM_033071.3) | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as COSV55111555; called by muse, mutect2, varscan2
- TMLHE | c.117C>G p.V39= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV57689701; called by muse, mutect2
- NCL | c.898+47G>A | Intron (SNP) | VAF 77/298 reads (26%) | catalogued as COSV59544954; called by muse, mutect2, varscan2
- PDHA2 | c.*2G>T | 3'UTR (SNP) | VAF 12/82 reads (15%) | catalogued as COSV54777404; called by muse, varscan2
- SSPOP | n.14414G>A | RNA (SNP) | VAF 39/167 reads (23%) | catalogued as rs753087145, COSV65137921; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 42/67 reads (63%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
